Somatic mutation profile of tumor specimen TCGA-D8-A1Y2-01A (aliquot TCGA-D8-A1Y2-01A-11D-A159-09) from TCGA case TCGA-D8-A1Y2, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 71.2 years (26,021 days).
Specimen TCGA-D8-A1Y2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5126229a-c6e7-4fbc-87ee-557d3c300b18.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D8-A1Y2-10A (Blood Derived Normal), aliquot TCGA-D8-A1Y2-10A-01D-A159-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9a5b9543-37db-44a3-862c-8699f21fae25

The open-access MAF lists 17 somatic variants for this specimen: 12 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 4, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 12/41 reads (29%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- RARA | c.857T>C p.F286S | Missense Mutation (SNP) | VAF 9/32 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54194067, COSV54195350; called by muse, mutect2, varscan2
- DYNC1H1 | c.1136G>A p.R379H | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.885); catalogued as COSV64134259; called by muse, mutect2, varscan2
- ERICH3 | c.2005C>T p.L669F | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.962); catalogued as COSV58611482; called by muse, mutect2, varscan2
- GPR3 | c.811G>A p.D271N | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.078); catalogued as COSV64995017; called by muse, mutect2, varscan2
- ITPR1 | c.7193A>G p.Y2398C (on ENST00000354582; = p.Y2343C on NM_002222.7) | Missense Mutation (SNP) | VAF 39/88 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56990190; called by muse, mutect2, varscan2
- KDM3B | c.4976G>A p.R1659H | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58689567; called by muse, mutect2, varscan2
- MAP4K5 | c.1069G>A p.E357K | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.755); catalogued as COSV50156556; called by muse, varscan2
- OR10Z1 | c.115C>G p.L39V | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.021); catalogued as COSV63525541; called by muse, mutect2, varscan2
- SHISA4 | c.268G>A p.A90T | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.7); catalogued as rs867436400, COSV62884677; called by muse, mutect2, varscan2
- TNNT2 | c.419G>A p.R140H | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1339922051, COSV52661246, COSV99372213; called by muse, mutect2
- TUBG1 | c.127G>A p.E43K | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.077); catalogued as COSV52221710; called by muse, mutect2, varscan2
- ARAP3 | c.2181C>T p.L727= | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as COSV53352103; called by muse, mutect2, varscan2
- EHD2 | c.1020G>C p.A340= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as COSV54409521, COSV99622224; called by muse, mutect2, varscan2
- KLK3 | c.585C>T p.F195= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as rs1383314041, COSV58101432; called by muse, mutect2, varscan2
- RTN4IP1 | c.363G>T p.R121= | Silent (SNP) | VAF 5/39 reads (13%) | catalogued as COSV64805761; called by muse, mutect2, varscan2
- OR2W5 | n.1141C>G | RNA (SNP) | VAF 4/9 reads (44%) | called by muse, mutect2, varscan2
